Gene-level copy-number profile of tumor specimen TCGA-XF-A9ST-01A from TCGA case TCGA-XF-A9ST, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 68.7 years (25,080 days).
Specimen TCGA-XF-A9ST-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.f381e105-6c34-4461-9ff7-78df19eae42e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XF-A9ST-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fd77f3d4-2ea7-4d85-b106-7939c0a19eda

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 2,372; copy number 2: 2,971; copy number 3: 15,008; copy number 4: 23,689; copy number 5: 10,813; copy number 6: 2,923; copy number 7: 1,485; copy number 8: 311; copy number 9: 56; copy number 10: 116; copy number 11: 36; copy number 13: 11; copy number 14: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XF-A9ST-01A-11D-A42D-01): tumor purity 0.87, ploidy 4, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 230 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:147,172,755–147,295,734, 1 gene, copy number 10 (within-gene range 5–10): AC242426.2.
- chr1:147,223,554–147,909,269, 18 genes, copy number 10–13 (within-gene range 4–13): RPL7AP15, CHD1L, LINC00624, AC242426.1, OR13Z1P, Y_RNA, OR13Z2P, OR13Z3P, BCL9, AC242628.1, ACP6, RN7SL261P, AC241644.1, GJA5, AC241644.3, AC241644.2, AC239801.1, GJA8.
- chr1:151,700,058–151,853,712, 20 genes, copy number 9–11: CELF3, AL589765.1, RIIAD1, RNU6-662P, AL589765.7, AL589765.3, MRPL9, OAZ3, AL589765.4, AL589765.2, AL589765.5, TDRKH, TDRKH-AS1, AL589765.6, LINGO4, RORC, C2CD4D, Y_RNA, C2CD4D-AS1, THEM5.
- chr1:160,537,073–162,868,815, 100 genes, copy number 10–14 (within-gene range 6–14) (broad region; genes not listed).
- chr1:165,476,838–165,827,755, 14 genes, copy number 10 (within-gene range 5–10): LRRC52-AS1, PRELID1P7, LRRC52, AL356441.2, AL356441.1, MGST3, ALDH9A1, Y_RNA, AL451074.3, AL451074.2, AL451074.1, AL451074.5, TMCO1, TMCO1-AS1.
- chr1:166,603,916–168,376,876, 46 genes, copy number 9–14 (within-gene range 8–14): FMO9P, FMO10P, RPL4P2, FMO11P, CNN2P10, POGK, TADA1, DUTP6, ILDR2, MAEL, RNA5SP65, AL158837.1, GPA33, STYXL2, AL451050.1, LINC01363, AL451050.2, POU2F1, AL136984.1, CD247, AL359962.3, AL359962.1, AL359962.2, AKR1D1P1, CREG1, AL031733.1, AL031733.2, RCSD1, MPZL1, ADCY10, Z99943.2, Z99943.1, MPC2, DCAF6, MIR1255B2, GCSHP5, GPR161, TIPRL, RPL34P1, AL021397.1, SFT2D2, ANKRD36BP1, RNU6-1310P, TBX19, AL022100.1, MIR557.
- chr1:170,748,573–171,593,511, 18 genes, copy number 11 (within-gene range 7–11): BX284613.2, MROH9, BX284613.1, FMO3, MIR1295A, MIR1295B, FMO6P, FMO2, AL021026.1, FMO1, Y_RNA, HMGB1P11, FMO4, TOP1P1, SRP14P4, GM2AP2, CYCSP53, PRRC2C.
- chr1:171,635,417–171,742,074, 4 genes, copy number 9 (within-gene range 5–9): MYOC, PFN1P1, RPL4P3, VAMP4.
- chr1:181,088,700–181,238,604, 4 genes, copy number 10: IER5, LINC01732, AL358393.1, LINC01699.
- chr5:51,886,688–52,282,859, 5 genes, copy number 9: RNA5SP182, KATNBL1P4, AC091903.1, LINC02118, RPS17P11.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
